Somatic mutation profile of tumor specimen 0DESTW from CCDI case PBBRFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.0 years (4,025 days).
Specimen 0DESTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 702a0e0a-4b9c-467e-99b7-ceef7a13ea13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DESTX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/645d0210-eb0d-465d-a8c7-813fafe2f1a1

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 151/1000 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 154/614 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COG8 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 225/565 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs776137291; called by muse, mutect2, varscan2
- MTOR | c.5857G>A p.V1953M | Missense Mutation (SNP) | VAF 296/723 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as CM154579, COSV63870213; called by muse, varscan2
- OR5K4 | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 65/1053 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs1408053978; called by muse, mutect2
- RYR2 | c.12811G>T p.V4271L | Missense Mutation (SNP) | VAF 74/636 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63709585; called by muse, mutect2, varscan2
- HS6ST1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 243/614 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- UNC13A | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 19/454 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by muse, mutect2
- TMEM117 | c.1455G>A p.S485= | Silent (SNP) | VAF 33/1327 reads (2%) | catalogued as COSV56915247; called by muse, mutect2
- PDE3A | c.1011+29G>A | Intron (SNP) | VAF 66/608 reads (11%) | catalogued as rs768082296, COSV100763003; called by muse, mutect2, varscan2
